Gene-level copy-number profile of specimen HCM-SANG-0271-D12-85A-01D-A80T-32 from HCMI case HCM-SANG-0271-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubular adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0271-D12-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 27af2529-8b4f-4f7a-8607-722540634293.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0271-D12-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/8d3df3f5-caff-4f29-b353-106deb81cd57

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 507; copy number 1: 3; copy number 2: 167; copy number 3: 5,039; copy number 4: 25,879; copy number 5: 14,242; copy number 6: 7,713; copy number 7: 3,066; copy number 8: 1,348; copy number 9: 58; copy number 11: 3; copy number 12: 300; copy number 13: 387; copy number 15: 4; copy number 17: 179.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 931 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:45,323,253–45,480,136, 3 genes, copy number 11: THAP12P9, AC108043.1, RNU6-931P.
- chr12:17,710,934–17,711,046, 1 gene, copy number 9: Y_RNA.
- chr12:23,108,458–26,833,194, 57 genes, copy number 9 (within-gene range 6–10): AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr20:30,214,765–64,327,972, 870 genes, copy number 12–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
